Somatic mutation profile of tumor specimen TCGA-AZ-6601-01A (aliquot TCGA-AZ-6601-01A-11D-1771-10) from TCGA case TCGA-AZ-6601, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage II; Age at diagnosis: 68.7 years (25,082 days).
Specimen TCGA-AZ-6601-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ab2d8cb-85dd-4405-adf1-c53674e00c23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AZ-6601-11A (Solid Tissue Normal), aliquot TCGA-AZ-6601-11A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92a1fff1-352b-46dd-a2fa-6ad7830b4b5d

The open-access MAF lists 2,470 somatic variants for this specimen: 1,713 protein-altering or splice-affecting, 605 silent, 152 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,500, Silent 605, Nonsense Mutation 80, 3'UTR 63, Frame Shift Del 54, Intron 42, Splice Site 28, Splice Region 25, Frame Shift Ins 21, 5'UTR 21, RNA 14, 5'Flank 8.

Variants (750 of 2,470; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP5 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 18/81 reads (22%) | catalogued as rs1025967277, COSV54536060, COSV99520309; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 61/252 reads (24%) | hotspot (GDC flag); catalogued as rs397515734, CM920029, COSV57320753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as rs786201856, CM920030, COSV57325157; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARSA | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199476382, CM160319, CM950096, COSV53350354; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- B2M | c.68-1G>T p.X23_splice | Splice Site (SNP) | VAF 30/62 reads (48%) | hotspot (GDC flag); catalogued as rs111947448, COSV62563163, COSV62563826; called by muse, mutect2, varscan2
- CACNA1F | c.3269+1G>A p.X1090_splice | Splice Site (SNP) | VAF 19/47 reads (40%) | catalogued as rs1064797371, COSV59903546; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAH5 | c.9346C>T p.R3116* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as rs1264701182, COSV54220096; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 20/108 reads (19%) | hotspot (GDC flag); catalogued as rs1362274408, COSV55920408; called by muse, mutect2, varscan2
- FGFR1 | c.1019C>T p.T340M (on ENST00000447712 / NM_023110.3; = p.T338M on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1064793123, CM0911318, COSV58331507; ClinVar: likely pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 54/239 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3312dup p.G1105Wfs*3 | Frame Shift Ins (INS) | VAF 22/114 reads (19%) | catalogued as rs267608092; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- MYH3 | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913617, CM061864, COSV56863939; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCO2 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28937598, CM001336, COSV52687476; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC2A1 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs387907313, CM121481, COSV65287245; ClinVar: risk factor / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 38/156 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 37/169 reads (22%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3628C>A p.L1210M | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs887150035, COSV55289623; called by muse, mutect2, varscan2
- AACS | c.1942G>A p.V648M | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs765733198, COSV55536128; called by muse, mutect2, varscan2
- AARS2 | c.2145+1G>T p.X715_splice | Splice Site (SNP) | VAF 53/183 reads (29%) | catalogued as COSV55114452; called by muse, mutect2, varscan2
- AASDH | c.3116C>T p.A1039V | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs1435782331; called by muse, mutect2
- ABCA10 | c.3287A>T p.D1096V | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV52221178; called by muse, mutect2, varscan2
- ABCA10 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.501); catalogued as COSV52221192; called by muse, mutect2, varscan2
- ABCA13 | c.14731C>A p.L4911M | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68945987; called by muse, mutect2, varscan2
- ABCA4 | c.2538T>A p.D846E | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100933010; called by muse, mutect2, varscan2
- ABCA7 | c.5434C>T p.R1812C | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs746810662, COSV54028188; called by muse, mutect2, varscan2
- ABCA7 | c.5572G>A p.V1858M | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as rs1012809838, COSV54028201; called by muse, varscan2
- ABCA7 | c.5836G>A p.V1946M | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); catalogued as COSV54028168; called by muse, mutect2, varscan2
- ABCB1 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV55949791; called by muse, mutect2, varscan2
- ABCB8 | c.937G>T p.G313C (on ENST00000297504 / NM_001282291.2; = p.G296C on NM_007188.5) | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52503998; called by muse, mutect2, varscan2
- ABCC4 | c.1574T>C p.L525P | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV100972195; called by muse, mutect2, varscan2
- ABCC5 | c.1274G>A p.G425D | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV55589220; called by muse, mutect2, varscan2
- ABCC9 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53969213; called by muse, mutect2, varscan2
- ABCF3 | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as rs779011033, COSV53052144; called by muse, mutect2, varscan2
- ABCG4 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV56643367; called by muse, mutect2, varscan2
- ABHD16A | c.1543G>A p.V515M | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs758057318, COSV65451449; called by muse, mutect2, varscan2
- ABHD16A | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs780015445, COSV65451701; called by muse, mutect2, varscan2
- ABT1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51291093; called by muse, mutect2, varscan2
- ABTB1 | c.1277C>T p.A426V (on ENST00000232744 / NM_172027.3; = p.A284V on NM_032548.3) | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs148820470; called by muse, mutect2, varscan2
- AC004922.1 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.941); catalogued as COSV53163172; called by muse, mutect2, varscan2
- AC008397.2 | c.222G>A p.W74* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100828165; called by muse, mutect2
- AC011455.2 | c.1342A>G p.I448V | Missense Mutation (SNP) | VAF 64/368 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as COSV99671085; called by muse, mutect2, varscan2
- AC092143.1 | c.1598C>T p.T533M | Missense Mutation (SNP) | VAF 69/294 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs770484819, COSV59247668; called by muse, mutect2, varscan2
- ACACB | c.4892A>G p.E1631G | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100622228; called by muse, mutect2, varscan2
- ACAD8 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs374584216, CM063823, COSV99844106; called by muse, mutect2, varscan2
- ACAN | c.2431C>T p.P811S | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.632); catalogued as COSV61359475; called by muse, mutect2, varscan2
- ACAP3 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV57639883; called by muse, mutect2, varscan2
- ACAP3 | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs757717274, COSV61222058; called by muse, mutect2, varscan2
- ACE | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1249291422, COSV52005983; called by muse, mutect2, varscan2
- ACO1 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 46/213 reads (22%) | catalogued as rs142015075; called by muse, mutect2, varscan2
- ACOX2 | c.1741A>G p.I581V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV100249962; called by mutect2, varscan2
- ACP2 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199935537, COSV57042328; called by muse, mutect2, varscan2
- ACRBP | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs763758076, COSV57524785; called by muse, mutect2, varscan2
- ACSF3 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144907664, COSV58078018; called by muse, mutect2, varscan2
- ACSM5 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750548939, COSV59371010; called by muse, mutect2, varscan2
- ACSS1 | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 17/398 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1027957028; called by muse, mutect2
- ACTN1 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs750397684, COSV51989361; called by muse, mutect2, varscan2
- ACVR1B | c.1381C>T p.Q461* | Nonsense Mutation (SNP) | VAF 36/155 reads (23%) | catalogued as COSV57776537; called by muse, mutect2, varscan2
- ACVR1B | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs757836305, COSV57775597; called by muse, mutect2, varscan2
- ADAM22 | c.2357G>T p.S786I | Missense Mutation (SNP) | VAF 17/263 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as COSV55975372; called by muse, mutect2
- ADAMTS10 | c.1041-1G>T p.X347_splice | Splice Site (SNP) | VAF 58/229 reads (25%) | catalogued as COSV54354094; called by muse, mutect2, varscan2
- ADAMTS3 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs773642539, COSV54392291; called by mutect2, varscan2
- ADAMTS9 | c.4247G>A p.R1416Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as rs755716045, COSV55779818; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2010G>T p.W670C | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101001172, COSV65897056; called by muse, mutect2, varscan2
- ADAMTSL2 | c.412+1G>A p.X138_splice | Splice Site (SNP) | VAF 13/63 reads (21%) | catalogued as COSV63203872; called by muse, mutect2, varscan2
- ADARB1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as rs774995629, COSV62343879; called by muse, mutect2, varscan2
- ADCY5 | c.2651C>T p.S884L | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs529379333, COSV59196989; called by muse, mutect2, varscan2
- ADCY7 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs569713104, COSV54265638; called by muse, mutect2, varscan2
- ADCY7 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as COSV54266165; called by muse, mutect2, varscan2
- ADD1 | c.1343T>C p.L448P | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53268556; called by muse, mutect2, varscan2
- ADGRA3 | c.194G>A p.C65Y | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57546114; called by muse, mutect2, varscan2
- ADGRD1 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs144030317; called by muse, mutect2, varscan2
- ADGRE5 | c.275T>C p.V92A | Missense Mutation (SNP) | VAF 62/274 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as COSV54410039; called by muse, mutect2, varscan2
- ADGRF3 | c.376G>A p.V126I (on ENST00000311519 / NM_001145168.1; = p.V67I on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as rs757218422, COSV61049939; called by muse, mutect2, varscan2
- ADGRG4 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as rs763907204, COSV54954261; called by muse, varscan2
- AFAP1L1 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs571245239, COSV99695578; called by muse, mutect2, varscan2
- AFAP1L1 | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV57043631; called by muse, mutect2, varscan2
- AFF1 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1408856593, COSV57119218; called by muse, mutect2, varscan2
- AGTR2 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782155285, COSV64156404; called by muse, mutect2, varscan2
- AGXT | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 51/291 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1437693420, COSV56753823; called by muse, mutect2, varscan2
- AHCY | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); catalogued as rs199533546, COSV54152885; called by muse, mutect2, varscan2
- AHCYL1 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.191); catalogued as COSV63208540; called by muse, mutect2, varscan2
- AHR | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as rs545782208, COSV54123074; ClinVar: uncertain significance; called by mutect2, varscan2
- AIFM1 | c.1784G>A p.G595D | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as COSV99780704; called by muse, mutect2
- AIM2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 58/267 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs748140754, COSV63699140; called by muse, mutect2, varscan2
- AK9 | c.1165G>T p.G389* | Nonsense Mutation (SNP) | VAF 20/166 reads (12%) | catalogued as COSV99572300; called by mutect2, varscan2
- AKAP1 | c.2243C>A p.S748Y | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100532595; called by mutect2, varscan2
- AKAP11 | c.1838G>A p.S613N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV50297817, COSV99213412; called by muse, mutect2, varscan2
- AKAP6 | c.3508C>A p.L1170I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99797857; called by muse, mutect2, varscan2
- AKAP9 | c.4117C>T p.Q1373* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as COSV62340681, COSV62344277; called by muse, mutect2, varscan2
- AL121758.1 | c.269G>T p.R90M | Missense Mutation (SNP) | VAF 21/86 reads (24%) | PolyPhen possibly damaging (0.711); catalogued as COSV67937925, COSV67938056; called by muse, mutect2, varscan2
- AL136295.1 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs890918250, COSV55779223; called by muse, mutect2, varscan2
- ALDH4A1 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139487658, COSV51892081; called by muse, mutect2, varscan2
- ALDH6A1 | c.424C>A p.L142I | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.606); catalogued as COSV63245825, COSV63246254; called by muse, mutect2, varscan2
- ALG1 | c.208+1G>A p.X70_splice | Splice Site (SNP) | VAF 57/254 reads (22%) | catalogued as rs1313166263, COSV52157400; called by muse, mutect2, varscan2
- ALK | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.026); catalogued as rs374276783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX5 | c.1597C>T p.R533W | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); catalogued as rs1489619790, COSV65552115; called by muse, mutect2, varscan2
- ALS2CL | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs761173942, COSV59672940; called by muse, mutect2, varscan2
- AMBRA1 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as COSV54052834; called by muse, mutect2, varscan2
- AMER3 | c.2113C>A p.L705I | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs934358617; called by muse, mutect2
- AMOTL1 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs201579435, COSV100133611; called by muse, varscan2
- AMOTL2 | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781488712, COSV51438704; called by muse, mutect2, varscan2
- ANGPTL2 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 37/159 reads (23%) | catalogued as rs375360881; called by muse, mutect2, varscan2
- ANK1 | c.615G>A p.T205= | Splice Region (SNP) | VAF 11/38 reads (29%) | catalogued as rs550448129, COSV55879780; called by muse, mutect2, varscan2
- ANK3 | c.6788C>T p.A2263V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV55044299; called by mutect2, varscan2
- ANK3 | c.6173A>C p.K2058T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as rs755965150, COSV99778024; called by muse, mutect2, varscan2
- ANKRD24 | c.2911G>A p.V971M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.227); catalogued as COSV53669852; called by muse, mutect2
- ANKRD28 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs758460133, COSV67517766; called by muse, mutect2, varscan2
- ANKRD33 | c.343G>A p.V115M (on ENST00000340970 / NM_001304459.2; = p.V240M on NM_182608.4) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as rs368101868; called by muse, mutect2
- ANKRD50 | c.3599C>T p.T1200M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs748993444, COSV101538872; called by muse, mutect2, varscan2
- ANKZF1 | c.1876C>T p.R626W | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs575269311, COSV55476243; called by muse, mutect2, varscan2
- ANXA8 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 124/654 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1325972402; called by muse, mutect2, varscan2
- AOPEP | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1027115168, COSV52917346; called by muse, mutect2, varscan2
- AP002748.5 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs966335429, COSV59148272; called by muse, mutect2, varscan2
- APBB1 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs368805217; called by muse, mutect2, varscan2
- APEX1 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51657485; called by muse, mutect2, varscan2
- APOBEC3B | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs747995529, COSV59840816; called by muse, mutect2, varscan2
- APOL3 | c.389T>G p.L130R (on ENST00000349314 / NM_145640.2; = p.L59R on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV62579595; called by muse, mutect2, varscan2
- ARAF | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 133/257 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV51692296; called by muse, mutect2, varscan2
- ARAP3 | c.4432C>T p.R1478W | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.109); catalogued as rs370453653; called by muse, mutect2, varscan2
- ARHGAP11B | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 64/303 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs567608269, COSV101451760; called by muse, mutect2, varscan2
- ARHGAP20 | c.154C>A p.L52M | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as rs1475868181, COSV52812574; called by muse, mutect2, varscan2
- ARHGAP21 | c.33G>T p.E11D | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.028); catalogued as COSV64543309; called by muse, mutect2, varscan2
- ARHGAP31 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs376265481; called by muse, mutect2, varscan2
- ARHGAP45 | c.2828C>A p.P943H | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53123934; called by muse, mutect2, varscan2
- ARHGAP6 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs772160289, COSV61626940; called by muse, mutect2, varscan2
- ARHGEF11 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1253713510, COSV100810391, COSV63811872; called by muse, mutect2, varscan2
- ARHGEF17 | c.3985C>T p.R1329C | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as rs1565206681, COSV55231896; called by muse, mutect2, varscan2
- ARHGEF19 | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV54616348; called by muse, mutect2, varscan2
- ARHGEF3 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs1314753114, COSV56324753; called by muse, mutect2, varscan2
- ARHGEF40 | c.3764C>T p.A1255V | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs376203053; called by muse, mutect2, varscan2
- ARID1A | c.2248C>T p.R750* | Nonsense Mutation (SNP) | VAF 68/186 reads (37%) | catalogued as COSV100250607, COSV61371935; called by muse, mutect2, varscan2
- ARID1B | c.5935C>T p.P1979S | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1361439044, COSV51659256; called by muse, mutect2, varscan2
- ARID5A | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV62591048; called by muse, mutect2, varscan2
- ARMC8 | c.1751C>T p.A584V (on ENST00000469044 / NM_001363941.2; = p.A570V on NM_015396.6) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100509375; called by muse, mutect2, varscan2
- ARMCX2 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 63/99 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs782811435, COSV57529832; called by muse, mutect2, varscan2
- ARMH1 | c.1243A>C p.N415H | Missense Mutation (SNP) | VAF 73/317 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.371); catalogued as COSV100679576; called by muse, mutect2, varscan2
- ARMH4 | c.738G>T p.E246D | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV99957506; called by muse, mutect2
- ARPC2 | c.186A>C p.K62N | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.421); catalogued as COSV55284389; called by muse, mutect2, varscan2
- ARRB1 | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63575192; called by muse, mutect2, varscan2
- ARRDC2 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV55843875; called by muse, mutect2, varscan2
- ASAP2 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs1209147766, COSV55628638; called by muse, mutect2, varscan2
- ASCC3 | c.1398C>T p.I466= | Splice Region (SNP) | VAF 13/56 reads (23%) | catalogued as rs202070959, COSV100225095; called by mutect2, varscan2
- ASPG | c.1600G>A p.G534R | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV71933747; called by muse, mutect2, varscan2
- ASPHD2 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 70/236 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53218770; called by muse, mutect2, varscan2
- ASXL1 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV60106884; called by muse, mutect2, varscan2
- ATAD2B | c.920del p.K307Rfs*57 | Frame Shift Del (DEL) | VAF 14/77 reads (18%) | catalogued as rs1558707706; called by mutect2, pindel, varscan2
- ATE1 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs755232792, COSV56435625; called by mutect2, varscan2
- ATG2A | c.4735C>T p.R1579C | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1294786629, COSV65967201; called by muse, mutect2, varscan2
- ATN1 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 55/246 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.148); catalogued as rs782462592, COSV63110856; called by muse, mutect2, varscan2
- ATP10A | c.2635C>T p.R879C | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as rs763611613, COSV63512846, COSV63515586; called by muse, mutect2, varscan2
- ATP10A | c.812A>G p.N271S | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63516558; called by muse, mutect2, varscan2
- ATP11C | c.1284C>A p.C428* | Nonsense Mutation (SNP) | VAF 29/196 reads (15%) | catalogued as COSV59562770; called by muse, mutect2, varscan2
- ATP1A3 | c.2716G>A p.G906R (on ENST00000545399 / NM_001256214.2; = p.G893R on NM_152296.5) | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as CM145551, COSV100131885; called by muse, mutect2, varscan2
- ATP2A3 | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs1377456684, COSV59228444; called by muse, mutect2, varscan2
- ATP2B2 | c.2669A>G p.Q890R (on ENST00000352432; = p.Q856R on NM_001683.5) | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as COSV100660179, COSV59495027; called by muse, mutect2
- ATP2B4 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1292104307, COSV58176951; called by muse, mutect2, varscan2
- ATP6V0A4 | c.926T>G p.L309R | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100022540; called by muse, mutect2, varscan2
- ATP6V0D1 | c.558C>A p.Y186* | Nonsense Mutation (SNP) | VAF 47/230 reads (20%) | catalogued as COSV52097486; called by muse, mutect2, varscan2
- ATP8B1 | c.1135G>T p.D379Y | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV52175130; called by muse, mutect2, varscan2
- ATXN3 | c.307A>G p.R103G | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV61494919; called by muse, mutect2, varscan2
- ATXN7L1 | c.1847A>G p.H616R | Missense Mutation (SNP) | VAF 184/983 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as COSV66300154; called by muse, varscan2
- AUP1 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746000640, COSV57817898; called by muse, mutect2, varscan2
- AVPI1 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 54/252 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs544820695, COSV65697467; called by muse, mutect2, varscan2
- AVPR1B | c.212T>G p.L71R | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as COSV100899295; called by muse, mutect2
- B3GALT1 | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59908551; called by muse, mutect2, varscan2
- B3GNT4 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs570110830, COSV57336171; called by muse, mutect2, varscan2
- B3GNT6 | c.49C>A p.L17I | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV62828116; called by muse, mutect2, varscan2
- B4GALT7 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs926736424, COSV50353127; called by muse, mutect2, varscan2
- BACH1 | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV54518530; called by muse, mutect2, varscan2
- BACH2 | c.1790C>T p.S597L | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57590256; called by muse, mutect2, varscan2
- BACH2 | c.1291G>A p.V431M | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777694816, COSV57586787; called by muse, mutect2, varscan2
- BAHCC1 | c.5732G>A p.R1911Q | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as rs868951095, COSV57025536; called by muse, mutect2, varscan2
- BAIAP3 | c.2861T>C p.L954P | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50103906; called by muse, mutect2, varscan2
- BANK1 | c.858G>T p.K286N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV100535774; called by muse, mutect2, varscan2
- BATF | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54375717; called by muse, mutect2, varscan2
- BAZ1B | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 78/291 reads (27%) | catalogued as rs1554575021, COSV59990649; called by muse, mutect2, varscan2
- BBX | c.1774G>A p.A592T | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs377165584; called by muse, mutect2, varscan2
- BCAS3 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as rs746825060, COSV101174998; called by muse, mutect2, varscan2
- BCL6 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs536118071, COSV51650474; called by muse, mutect2, varscan2
- BCL6B | c.1366C>T p.R456W | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748482678, COSV53427558; called by muse, mutect2, varscan2
- BCL9 | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 20/80 reads (25%) | catalogued as COSV52343441; called by muse, mutect2, varscan2
- BCL9L | c.1354del p.Q452Sfs*11 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as rs756382429; called by mutect2, pindel, varscan2
- BCL9L | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52681952; called by muse, mutect2, varscan2
- BCR | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.673); catalogued as COSV59930494; called by muse, mutect2, varscan2
- BEND4 | c.996G>T p.E332D | Missense Mutation (SNP) | VAF 62/245 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV72469060; called by muse, mutect2, varscan2
- BGLAP | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs182971055, COSV52744962; called by muse, mutect2, varscan2
- BICDL1 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.922); catalogued as rs199743447, COSV66907589; called by muse, mutect2, varscan2
- BICDL2 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs1329912299, COSV54156097; called by muse, mutect2, varscan2
- BICRA | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 103/432 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV67604554; called by muse, mutect2, varscan2
- BIRC3 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54815220; called by muse, mutect2, varscan2
- BMP1 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as rs770440497, COSV60478574, COSV60480301; called by muse, mutect2, varscan2
- BMP15 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs782453307, COSV53140338; called by muse, mutect2, varscan2
- BMPER | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV51816828; called by muse, mutect2, varscan2
- BOLA3 | c.285G>A p.M95I | Missense Mutation (SNP) | VAF 112/484 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99768073; called by muse, varscan2
- BPIFB1 | c.223A>G p.S75G | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.109); catalogued as COSV53606346; called by muse, mutect2, varscan2
- BRCA2 | c.8971C>T p.R2991C | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.083); catalogued as rs751787816, COSV66452721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD3 | c.124A>G p.M42V | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1282240346, COSV100324634; called by muse, mutect2
- BRINP1 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.978); catalogued as rs1043377, COSV56291420; called by muse, mutect2, varscan2
- BRPF3 | c.2111C>T p.P704L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV60207031; called by muse, mutect2, varscan2
- BRWD3 | c.4261G>A p.A1421T | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100955598; called by muse, mutect2, varscan2
- BSDC1 | c.722T>C p.V241A | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100344333; called by muse, mutect2, varscan2
- BSN | c.8027C>T p.T2676M | Missense Mutation (SNP) | VAF 105/436 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375618747; called by muse, mutect2, varscan2
- BTBD11 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); catalogued as rs369384423, COSV55023111; called by muse, mutect2, varscan2
- BTBD8 | c.3196G>A p.D1066N (on ENST00000636805 / NM_001376131.1; = p.D553N on NM_015237.4) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776052910, COSV64885428; called by mutect2, varscan2
- BTN2A1 | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.54); catalogued as COSV57003230; called by muse, mutect2, varscan2
- BZW1 | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63349656; called by muse, mutect2, varscan2
- C11orf80 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs371552584; called by muse, mutect2, varscan2
- C12orf43 | c.653T>A p.V218D | Missense Mutation (SNP) | VAF 105/382 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.124); catalogued as COSV99981943; called by muse, mutect2, varscan2
- C16orf72 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775739454, COSV59915691; called by muse, mutect2, varscan2
- C17orf80 | c.1082C>T p.T361M | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs752447234, COSV52145990; called by muse, mutect2, varscan2
- C19orf47 | c.664del p.R222Afs*74 | Frame Shift Del (DEL) | VAF 48/249 reads (19%) | catalogued as COSV63511139; called by mutect2, pindel, varscan2
- C21orf58 | c.764A>C p.Q255P | Missense Mutation (SNP) | VAF 67/356 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52449427, COSV52449882; called by muse, mutect2, varscan2
- CA6 | c.671G>A p.C224Y | Missense Mutation (SNP) | VAF 79/276 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66262029; called by muse, mutect2, varscan2
- CABIN1 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV54080941; called by muse, mutect2, varscan2
- CABIN1 | c.5639G>A p.R1880H | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.572); catalogued as rs139783753; called by muse, mutect2, varscan2
- CACNA1A | c.3787G>A p.A1263T | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV64196405; called by muse, mutect2, varscan2
- CACNA1A | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1057524457, COSV64196421; ClinVar: uncertain significance; called by muse, mutect2
- CACNA1C | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59728957, COSV59785524; called by muse, mutect2, varscan2
- CACNA1E | c.4781G>A p.R1594H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436277931, COSV62382452; called by muse, mutect2, varscan2
- CACNA1F | c.2017C>T p.L673F | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59904144; called by muse, mutect2, varscan2
- CACNA1H | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 21/246 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1478477776, COSV100673666, COSV61988583; called by muse, mutect2
- CACNA1H | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs199664795, COSV61988600; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CALD1 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773676427, COSV62647273; called by muse, mutect2, varscan2
- CAMTA2 | c.2276C>A p.P759H | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100772305; called by muse, mutect2, varscan2
- CAND2 | c.2863del p.V955Wfs*12 (on ENST00000456430 / NM_001162499.2; = p.V862Wfs*12 on NM_012298.3) | Frame Shift Del (DEL) | VAF 27/105 reads (26%) | catalogued as rs780431641; called by mutect2, pindel, varscan2
- CAPN10 | c.737G>T p.R246L | Missense Mutation (SNP) | VAF 88/360 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as COSV99549882; called by muse, varscan2
- CAPN12 | c.1813G>A p.G605R | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs144459133; called by muse, mutect2
- CARD10 | c.2197C>T p.R733* | Nonsense Mutation (SNP) | VAF 19/138 reads (14%) | catalogued as rs144108378; called by muse, mutect2, varscan2
- CASK | c.1510A>G p.T504A | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV100586791; called by muse, mutect2, varscan2
- CASKIN2 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 46/297 reads (15%) | catalogued as COSV100395237; called by muse, mutect2, varscan2
- CASP8AP2 | c.2222G>A p.G741D | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV52746577; called by muse, mutect2, varscan2
- CBL | c.2603G>T p.G868V | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50629615; called by muse, mutect2
- CBX6 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53320731; called by muse, mutect2, varscan2
- CBY2 | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.035); catalogued as rs1453986677, COSV60117059; called by muse, varscan2
- CBY2 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60117963, COSV60118038; called by muse, varscan2
- CC2D1B | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746033572, COSV52559924; called by muse, mutect2, varscan2
- CCDC110 | c.155C>A p.P52Q | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100293623; called by muse, mutect2, varscan2
- CCDC57 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 14/392 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.343); catalogued as rs1227991802; called by muse, mutect2
- CCDC69 | c.231+1G>A p.X77_splice | Splice Site (SNP) | VAF 73/272 reads (27%) | catalogued as rs749326891, COSV100815065; called by muse, varscan2
- CCDC77 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs374200726; called by muse, mutect2, varscan2
- CCDC85A | c.1442C>A p.P481H | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV101339352; called by muse, mutect2, varscan2
- CCDC88B | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV57265847; called by muse, mutect2, varscan2
- CCDC88B | c.3319C>T p.R1107W | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs908358077, COSV57265851; called by muse, mutect2, varscan2
- CCDC93 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs377718905; called by muse, mutect2, varscan2
- CCNB1 | c.785A>G p.Y262C | Missense Mutation (SNP) | VAF 36/248 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1561314968, COSV56509850; called by muse, mutect2, varscan2
- CCND1 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs200179137, COSV99919159; called by muse, varscan2
- CCNI | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs779499819, COSV52959606; called by muse, mutect2, varscan2
- CCNJ | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs147719412; called by muse, mutect2, varscan2
- CCNL2 | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV68766534; called by muse, mutect2
- CD207 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.751); catalogued as rs527591997, COSV69651979; called by muse, mutect2, varscan2
- CD63 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.773); catalogued as rs200393279; called by muse, mutect2
- CDC42EP1 | c.1094G>A p.S365N | Missense Mutation (SNP) | VAF 60/220 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV50756307; called by muse, mutect2, varscan2
- CDH12 | c.1766T>C p.V589A | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1301771788, COSV101200997; called by muse, mutect2, varscan2
- CDH18 | c.1678G>A p.V560I | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV56913399, COSV56917707; called by muse, mutect2
- CDH2 | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.024); catalogued as COSV99295343; called by muse, varscan2
- CDH23 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as rs1235821368, COSV54931817; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH4 | c.2326G>A p.V776I | Missense Mutation (SNP) | VAF 17/229 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); catalogued as rs142330895; called by muse, mutect2
- CDHR4 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as rs201296837, COSV58526098; called by muse, mutect2, varscan2
- CDK14 | c.652T>C p.C218R (on ENST00000380050 / NM_001287135.2; = p.C200R on NM_012395.3) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99723527; called by muse, mutect2, varscan2
- CDR2 | c.775C>T p.Q259* | Nonsense Mutation (SNP) | VAF 11/73 reads (15%) | catalogued as COSV51676073; called by muse, mutect2, varscan2
- CEACAM16 | c.703C>A p.R235S | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV69186637; called by muse, mutect2, varscan2
- CEACAM16 | c.1258C>A p.Q420K | Missense Mutation (SNP) | VAF 37/218 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.621); catalogued as COSV69186642; called by muse, mutect2, varscan2
- CEACAM4 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs201492288, COSV55731164; called by muse, mutect2, varscan2
- CEBPE | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99247303; called by muse, mutect2, varscan2
- CELA1 | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs778795147, COSV53329711; called by muse, mutect2, varscan2
- CELF3 | c.904G>A p.G302R | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs779202939, COSV99309975; called by muse, mutect2, varscan2
- CELSR1 | c.6371C>T p.T2124M | Missense Mutation (SNP) | VAF 63/245 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs771037022, COSV53094051; called by muse, mutect2, varscan2
- CELSR2 | c.7414C>T p.R2472C | Missense Mutation (SNP) | VAF 70/313 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771008996, COSV54767020; called by muse, mutect2, varscan2
- CENPI | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54502076; called by muse, mutect2, varscan2
- CEP131 | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs556177324, COSV99487762; called by muse, mutect2, varscan2
- CEP131 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs151144885; called by muse, mutect2, varscan2
- CEP192 | c.5174G>T p.R1725M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV58063050; called by muse, mutect2, varscan2
- CEP250 | c.7153G>A p.A2385T | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as COSV100698713; called by muse, mutect2, varscan2
- CEP55 | c.323C>G p.T108R | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV65184975; called by muse, mutect2, varscan2
- CERS5 | c.224G>A p.C75Y | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1266795757, COSV58188937; called by muse, mutect2, varscan2
- CFAP206 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs367568626; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.588G>T p.K196N | Missense Mutation (SNP) | VAF 71/310 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51591727; called by muse, mutect2, varscan2
- CFAP65 | c.360C>T p.P120= (on ENST00000341552 / NM_194302.4; = p.P55= on NM_152389.4) | Splice Region (SNP) | VAF 55/187 reads (29%) | catalogued as rs368785817; called by muse, mutect2, varscan2
- CFH | c.2035A>C p.T679P | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100808679; called by muse, mutect2, varscan2
- CGNL1 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777379043, COSV55566743, COSV99847666; called by muse, mutect2, varscan2
- CGNL1 | c.3092C>T p.A1031V | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as COSV55566763; called by muse, mutect2, varscan2
- CHD3 | c.4183C>A p.P1395T | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57874447; called by muse, mutect2, varscan2
- CHD3 | c.5591T>C p.V1864A (on ENST00000330494 / NM_001005273.3; = p.V1830A on NM_005852.4) | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV57874457; called by muse, mutect2, varscan2
- CHD4 | c.4370C>T p.P1457L (on ENST00000357008 / NM_001363606.2; = p.P1470L on NM_001273.5) | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58899578; called by muse, mutect2, varscan2
- CHD6 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761355563, COSV58553866; called by muse, mutect2, varscan2
- CHGA | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.324); catalogued as rs200937569, COSV53663026; called by muse, mutect2, varscan2
- CHI3L1 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55137861; called by muse, mutect2, varscan2
- CHPF2 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs766740377, COSV50390507; called by muse, varscan2
- CHRM4 | c.1282A>T p.S428C | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV100550978; called by muse, mutect2, varscan2
- CHRNA3 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 119/252 reads (47%) | catalogued as COSV58774039, COSV58774850; called by muse, mutect2, varscan2
- CHRNA3 | c.760C>T p.L254F | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.232); catalogued as COSV58774861; called by muse, varscan2
- CHRNA3 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766076436, COSV58775382; called by muse, varscan2
- CHRND | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 88/418 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51318550; called by muse, varscan2
- CHRNG | c.318G>T p.M106I | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV99285480; called by muse, mutect2, varscan2
- CHST15 | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as rs763384902, COSV60564208; called by muse, mutect2, varscan2
- CIAO3 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1169214942, COSV52401819; called by muse, mutect2, varscan2
- CIAO3 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs766170341, COSV52401831; called by muse, varscan2
- CIC | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs532264982, COSV50607638; called by muse, mutect2, varscan2
- CILP2 | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1166208565, COSV52274406; called by muse, mutect2, varscan2
- CIT | c.3256C>T p.R1086C | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55865176; called by muse, mutect2, varscan2
- CLASP2 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV56281075; called by muse, mutect2, varscan2
- CLASRP | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); catalogued as rs759794192, COSV55515863; called by muse, mutect2, varscan2
- CLCN4 | c.1605G>T p.L535F | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV101073610; called by muse, mutect2, varscan2
- CLCN6 | c.2356G>A p.D786N | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.068); catalogued as rs777943239, COSV56737809; called by muse, mutect2, varscan2
- CLCNKB | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs748423128, CM071615, COSV65160348; called by muse, varscan2
- CLCNKB | c.1633G>A p.V545M | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs773177291, COSV65153151; called by muse, mutect2, varscan2
- CLDN4 | c.322C>A p.L108M | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV99936287; called by muse, mutect2, varscan2
- CLEC10A | c.464A>C p.Q155P (on ENST00000254868 / NM_182906.4; = p.Q128P on NM_006344.4) | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV54700952; called by muse, mutect2, varscan2
- CLN3 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.321); catalogued as COSV100112222; called by muse, mutect2, varscan2
- CLNK | c.1238G>A p.C413Y | Missense Mutation (SNP) | VAF 71/263 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57014189; called by muse, mutect2, varscan2
- CLSTN1 | c.1978G>A p.V660I (on ENST00000377298 / NM_001009566.3; = p.V650I on NM_014944.4) | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs560870976, COSV63647845; called by muse, mutect2, varscan2
- CLSTN2 | c.1727G>T p.G576V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.198); catalogued as COSV71720481; called by muse, mutect2, varscan2
- CLYBL | c.992T>C p.V331A | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV100184551; called by muse, mutect2, varscan2
- CMTM8 | c.308C>A p.P103H | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56776871; called by muse, mutect2, varscan2
- CNBP | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.345); catalogued as COSV69654550; called by muse, mutect2, varscan2
- CNGA4 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1364721825, COSV66005665; called by muse, mutect2, varscan2
- CNKSR1 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 46/204 reads (23%) | catalogued as rs200619424, COSV64163188, COSV64163595; called by muse, mutect2, varscan2
- CNOT10 | c.1238G>A p.G413D | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.879); catalogued as COSV59391681; called by muse, mutect2, varscan2
- CNPPD1 | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55406801, COSV55408658; called by muse, mutect2, varscan2
- CNST | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs1327656524, COSV63621717; called by muse, mutect2, varscan2
- CNTN5 | c.428A>T p.D143V | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV54305244; called by muse, mutect2, varscan2
- CNTNAP1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147205771, COSV52849690; called by muse, mutect2, varscan2
- CNTNAP3 | c.2591C>T p.T864M | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as rs1170792150, COSV99903986; called by muse, mutect2, varscan2
- COA1 | c.146T>C p.L49S | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as COSV56241508; called by muse, mutect2, varscan2
- COG5 | c.1814C>T p.P605L (on ENST00000347053 / NM_001379512.1; = p.P626L on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV51748854; called by muse, mutect2, varscan2
- COL1A2 | c.704G>A p.G235D | Missense Mutation (SNP) | VAF 61/321 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM156283, COSV99798389; called by muse, mutect2, varscan2
- COL21A1 | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 26/103 reads (25%) | catalogued as rs368852095; called by muse, mutect2, varscan2
- COL23A1 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs780431788, COSV101177977; called by muse, mutect2, varscan2
- COL27A1 | c.2087C>A p.P696H | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV61925273; called by muse, mutect2, varscan2
- COL2A1 | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1326204674, COSV61529951; called by muse, mutect2, varscan2
- COL3A1 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as rs760324242, COSV58584331; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A4 | c.3155A>C p.E1052A | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.023); catalogued as COSV61631478; called by muse, mutect2, varscan2
- COL8A1 | c.2138G>T p.R713L | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV53733519; called by muse, mutect2, varscan2
- COLGALT1 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1463245724, COSV99394810; called by muse, mutect2
- COLGALT1 | c.1484G>A p.W495* | Nonsense Mutation (SNP) | VAF 28/156 reads (18%) | catalogued as COSV53108611; called by muse, mutect2, varscan2
- COMP | c.1972G>A p.G658R | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99721280, COSV99721399; called by muse, mutect2, varscan2
- CORO1B | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs769428845, COSV58167759; called by muse, mutect2, varscan2
- COX18 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.901); catalogued as rs186168799, COSV55720356; called by muse, mutect2, varscan2
- CPLANE1 | c.9550G>A p.V3184M | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs780349375, COSV57058221; called by muse, mutect2, varscan2
- CPNE2 | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs757386451, COSV51962134; called by muse, mutect2, varscan2
- CPNE4 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1355312776, COSV101456545; called by muse, mutect2, varscan2
- CPT1A | c.1630G>A p.V544M | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV55755284; called by muse, mutect2, varscan2
- CPT1B | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.085); catalogued as COSV56416243; called by muse, mutect2, varscan2
- CPXM2 | c.628A>G p.T210A | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as rs915611587, COSV99580861; called by muse, mutect2, varscan2
- CPXM2 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as COSV53860668; called by muse, mutect2, varscan2
- CR1 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.249); catalogued as COSV100887469, COSV65457809; called by muse, mutect2, varscan2
- CRACD | c.434T>C p.I145T | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99948454; called by muse, mutect2, varscan2
- CRACD | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV99948455; called by muse, mutect2
- CREB3L1 | c.689C>A p.P230H | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV99914803; called by muse, varscan2
- CREB3L4 | c.400G>T p.G134C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV99676573; called by muse, mutect2, varscan2
- CREBBP | c.6686G>A p.G2229D | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.051); catalogued as rs1194793942, COSV99268379; called by muse, mutect2, varscan2
- CREBBP | c.2517G>T p.Q839H | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.047); catalogued as COSV52121277; called by muse, mutect2, varscan2
- CREBBP | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52121155; called by muse, mutect2, varscan2
- CRNN | c.1325G>T p.W442L | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55121673; called by muse, mutect2, varscan2
- CROCC | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs144174614, COSV100978165, COSV65012941; called by muse, mutect2, varscan2
- CROCC | c.3509G>A p.R1170H | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as rs762876230, COSV65011671; called by muse, mutect2, varscan2
- CROCC | c.5624G>A p.R1875H | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs138053860; called by muse, varscan2
- CRTC2 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1450185712, COSV57842323; called by muse, mutect2, varscan2
- CRYBB3 | c.116G>A p.C39Y | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs1232309133, COSV53194444, COSV53195117; called by muse, mutect2, varscan2
- CSMD1 | c.8918T>C p.V2973A (on ENST00000520002; = p.V2972A on NM_033225.6) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV100142837; called by muse, mutect2, varscan2
- CSMD1 | c.7928C>T p.A2643V (on ENST00000520002; = p.A2642V on NM_033225.6) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs778074048, COSV59314425; called by muse, mutect2, varscan2
- CSMD2 | c.9614A>G p.D3205G | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.947); catalogued as COSV99585310; called by muse, mutect2
- CSMD3 | c.6015A>C p.R2005S (on ENST00000297405 / NM_001363185.1; = p.R1901S on NM_052900.3) | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.484); catalogued as COSV52162765; called by muse, mutect2, varscan2
- CSNK1E | c.256G>T p.G86W | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV63290507; called by muse, mutect2, varscan2
- CSRNP1 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs112383054, COSV56187931; called by muse, mutect2, varscan2
- CSRNP1 | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); catalogued as COSV99826667; called by muse, mutect2, varscan2
- CTCFL | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs995538553, COSV99712047; called by muse, mutect2, varscan2
- CTHRC1 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.777); catalogued as rs767061518, COSV57715382; called by muse, mutect2, varscan2
- CTNNB1 | c.767T>C p.I256T | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62698149; called by muse, mutect2, varscan2
- CTR9 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs754637023, COSV63728462; called by mutect2, varscan2
- CTTNBP2 | c.777A>G p.I259M | Missense Mutation (SNP) | VAF 138/575 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as rs1231073590, COSV50389497; called by muse, mutect2, varscan2
- CUEDC2 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs767718515, COSV56522825; called by muse, mutect2, varscan2
- CUL1 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 37/178 reads (21%) | catalogued as COSV57388144; called by muse, mutect2, varscan2
- CUL3 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs750769729, COSV52364044; called by muse, mutect2, varscan2
- CUL7 | c.3508C>T p.P1170S | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs867235173, COSV54815978; called by muse, mutect2, varscan2
- CUX2 | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.227); catalogued as rs1335073130, COSV55630214; called by muse, mutect2, varscan2
- CWC25 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs554680526; called by muse, mutect2, varscan2
- CXCR5 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1200379234, COSV52683823; called by muse, mutect2, varscan2
- CYP19A1 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749988131, COSV53058862; called by muse, mutect2, varscan2
- CYP2F1 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs770227087, COSV58527288; called by muse, mutect2, varscan2
- CYP4F11 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760671891, COSV56126668; called by muse, mutect2, varscan2
- DAAM2 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as rs533527149, COSV51311655; called by muse, mutect2, varscan2
- DAAM2 | c.1864G>A p.V622I | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as rs773228065, COSV51422292; called by muse, mutect2, varscan2
- DAG1 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 81/314 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58183765; called by muse, mutect2, varscan2
- DAPK2 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 129/249 reads (52%) | SIFT tolerated (0.43); PolyPhen benign (0.042); catalogued as rs749221840, COSV56045183; called by muse, mutect2, varscan2
- DCAF4L1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.651); catalogued as COSV60787077; called by muse, mutect2, varscan2
- DCBLD2 | c.1452T>C p.G484= | Splice Region (SNP) | VAF 18/65 reads (28%) | catalogued as COSV58789095; called by muse, mutect2, varscan2
- DCDC1 | c.3502G>A p.E1168K (on ENST00000597505 / NM_001367979.1; = p.E275K on NM_020869.3) | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as rs375684196; called by muse, mutect2, varscan2
- DCHS1 | c.2852G>A p.R951Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.986); catalogued as rs760791115, COSV100201389; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCHS2 | c.1336G>T p.G446C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as rs766901031, COSV59724467; called by mutect2, varscan2
- DCPS | c.350A>G p.H117R | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV55010661; called by muse, mutect2, varscan2
- DCST2 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs770129510, COSV55051380; called by muse, mutect2, varscan2
- DCTN1 | c.1427A>G p.E476G | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV62620337; called by muse, mutect2, varscan2
- DDA1 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.151); catalogued as rs374142177; called by muse, mutect2
- DDI1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as rs772774679, COSV56367219; called by muse, mutect2, varscan2
- DDX27 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759121430, COSV100873121, COSV65606512; called by muse, mutect2, varscan2
- DDX53 | c.1294A>G p.N432D | Missense Mutation (SNP) | VAF 67/125 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV60068899; called by muse, mutect2, varscan2
- DEGS2 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs765100971, COSV59783484; called by muse, mutect2, varscan2
- DELE1 | c.299G>T p.R100M | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99519623; called by muse, mutect2, varscan2
- DENND5A | c.3476G>A p.R1159Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200559278, COSV100063950; called by muse, mutect2, varscan2
- DES | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.498); catalogued as rs374144840; called by muse, mutect2, varscan2
- DGKG | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199698541; called by muse, mutect2, varscan2
- DHRS7 | c.238T>A p.S80T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs763203291, COSV53665863; called by muse, mutect2, varscan2
- DHTKD1 | c.2152C>T p.Q718* | Nonsense Mutation (SNP) | VAF 28/127 reads (22%) | catalogued as rs1362131325, COSV53803184, COSV53803416; called by muse, mutect2, varscan2
- DHX15 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1390375046, COSV61026699; called by muse, mutect2, varscan2
- DHX37 | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV58133973; called by muse, varscan2
- DHX57 | c.2195del p.L732Wfs*7 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs749610132; called by mutect2, varscan2
- DHX9 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100841212; called by muse, mutect2, varscan2
- DHX9 | c.2306G>A p.R769Q | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV62359156; called by muse, mutect2, varscan2
- DIP2A | c.4342C>T p.R1448W | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs759320654, COSV59476549; called by muse, varscan2
- DISP2 | c.3437G>A p.R1146H | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs374933710; called by muse, mutect2, varscan2
- DLGAP3 | c.550T>C p.S184P | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99332089; called by muse, mutect2, varscan2
- DLX4 | c.359C>T p.P120L (on ENST00000240306 / NM_138281.3; = p.P48L on NM_001934.3) | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53591537; called by muse, mutect2
- DMWD | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756284542, COSV52177461; called by muse, mutect2, varscan2
- DNAH1 | c.3997G>T p.D1333Y | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV70228413; called by muse, mutect2
- DNAH17 | c.4396G>A p.A1466T | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.576); catalogued as COSV67752989; called by muse, mutect2, varscan2
- DNAH2 | c.1359G>A p.W453* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as COSV50020871; called by muse, mutect2
- DNAH3 | c.11783C>T p.A3928V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.559); catalogued as COSV99764641; called by mutect2, varscan2
- DNAH3 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs570916220, COSV54511937, COSV99764645; called by mutect2, varscan2
- DNAH5 | c.6106C>T p.R2036C | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768503312, COSV54220109; called by muse, mutect2, varscan2
- DNAJC13 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753121018, COSV53449496; called by muse, mutect2, varscan2
- DNAJC16 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs772590021, COSV65448458; called by muse, mutect2, varscan2
- DNASE1L3 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as rs3772986, COSV59155736; called by muse, mutect2, varscan2
- DNASE2B | c.626T>C p.M209T | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV101042023; called by muse, mutect2, varscan2
- DNTT | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs943598334, COSV100960403; called by mutect2, varscan2
- DOP1B | c.5282C>A p.P1761H | Missense Mutation (SNP) | VAF 92/358 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as COSV67693096; called by muse, mutect2, varscan2
- DPY19L4 | c.329C>A p.P110H | Missense Mutation (SNP) | VAF 70/431 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101363053, COSV68963573; called by muse, mutect2, varscan2
- DPYD | c.1339G>T p.V447L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV64595874; called by muse, mutect2, varscan2
- DPYSL2 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV60783137; called by muse, mutect2, varscan2
- DPYSL4 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58306982; called by muse, mutect2, varscan2
- DSCAM | c.4382G>A p.R1461H | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1450850969, COSV68020951; called by muse, mutect2, varscan2
- DSCAML1 | c.2725G>A p.V909I (on ENST00000321322; = p.V849I on NM_020693.4) | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs761551361, COSV58386679; called by muse, mutect2, varscan2
- DSE | c.350C>A p.P117H | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59063355; called by muse, mutect2, varscan2
- DSP | c.8363C>T p.A2788V | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs748307773, COSV60939281; called by muse, mutect2, varscan2
- DSTYK | c.2060A>G p.D687G | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as rs1211919331, COSV100904439; called by muse, mutect2, varscan2
- DTWD1 | c.320C>T p.T107I | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52071546; called by muse, mutect2, varscan2
- DUOX1 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 98/604 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as rs370040367, COSV58484846; called by muse, mutect2, varscan2
- DUS1L | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs751958468, COSV60784437; called by muse, mutect2, varscan2
- DUS2 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1400372156, COSV62708311, COSV62710088; called by muse, mutect2
- DYNC1H1 | c.10181A>G p.K3394R | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64136410; called by muse, mutect2, varscan2
- DYNC1H1 | c.10964G>A p.R3655Q | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64136414; called by muse, mutect2, varscan2
- DYNC2I1 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 66/322 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as rs965500665, COSV68104477; called by muse, mutect2, varscan2
- DYNC2I2 | c.542G>A p.G181D | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63986719; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs199901698, COSV62567512; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2611G>A p.G871S | Missense Mutation (SNP) | VAF 57/237 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs749854216, COSV62567518; called by muse, mutect2, varscan2
- EEF1D | c.422C>A p.P141Q | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV52784352; called by muse, mutect2, varscan2
- EEF1G | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV100240034; called by muse, mutect2, varscan2
- EFEMP1 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs1310851571, COSV62615890; called by muse, mutect2, varscan2
- EFHD1 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs11550700, COSV51132345, COSV51133914; called by muse, mutect2, varscan2
- EFTUD2 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1206259660, COSV68182843; called by muse, mutect2, varscan2
- EGFL8 | c.-28-1G>A | Splice Site (SNP) | VAF 24/136 reads (18%) | catalogued as COSV100246774; called by muse, mutect2, varscan2
- EHMT1 | c.3543C>T p.D1181= | Splice Region (SNP) | VAF 17/60 reads (28%) | catalogued as rs1261628877, COSV66044706; called by muse, mutect2, varscan2
- EIF2D | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781957066, COSV55112155; called by muse, mutect2, varscan2
- EIF2D | c.854T>C p.L285P | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99662506; called by muse, mutect2, varscan2
- EIF4E2 | c.271-1G>T p.X91_splice | Splice Site (SNP) | VAF 64/316 reads (20%) | catalogued as COSV51471695, COSV99299308; called by muse, mutect2, varscan2
- EIF5 | c.271G>T p.G91* | Nonsense Mutation (SNP) | VAF 18/76 reads (24%) | catalogued as COSV53685028; called by muse, mutect2, varscan2
- ELL | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 22/88 reads (25%) | catalogued as COSV53210994; called by muse, mutect2, varscan2
- ELL2 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780151452, COSV99427156; called by muse, mutect2, varscan2
- ELMO3 | c.304T>C p.Y102H (on ENST00000652269; = p.Y49H on NM_024712.5) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62606389; called by muse, mutect2
- ELOA2 | c.671G>A p.S224N | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.142); catalogued as COSV99795799; called by muse, mutect2, varscan2
- EMC7 | c.464G>T p.W155L | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV56627590; called by muse, mutect2, varscan2
- EME1 | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs140304684; called by muse, mutect2, varscan2
- EMILIN1 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV66694621; called by muse, mutect2, varscan2
- EML5 | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as rs765131444, COSV100714995; called by muse, mutect2, varscan2
- ENKD1 | c.1037A>G p.D346G | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV54667194; called by muse, mutect2, varscan2
- ENOSF1 | c.505G>A p.A169T (on ENST00000340116 / NM_001354066.2; = p.A121T on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1048472827, COSV51892076; called by muse, mutect2, varscan2
- ENTPD8 | c.1198C>T p.R400W (on ENST00000371506 / NM_001033113.2; = p.R363W on NM_198585.3) | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs769068055, COSV58161639; called by muse, mutect2, varscan2
- EPB41L4A | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201722745; called by muse, mutect2, varscan2
- EPHA5 | c.683T>C p.V228A | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV56682832; called by muse, mutect2, varscan2
- EPHA6 | c.1082C>T p.T361I | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV101060691; called by muse, mutect2, varscan2
- EPHB4 | c.377T>G p.L126R | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.052); catalogued as COSV62268667; called by muse, mutect2, varscan2
- ERBB2 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 70/321 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.042); catalogued as COSV54068888; called by muse, mutect2, varscan2
- ERBB4 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs561236916, COSV53525744; called by muse, mutect2, varscan2
- ERCC4 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | catalogued as COSV61311757; called by muse, mutect2, varscan2
- ERF | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370521331; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 26/127 reads (20%) | catalogued as rs753821453; called by mutect2, varscan2
- ERN1 | c.1889G>A p.C630Y | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV70501684; called by muse, mutect2, varscan2
- ERVFRD-1 | c.200G>A p.S67N | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100977337; called by muse, mutect2, varscan2
- ESF1 | c.2523G>T p.Q841H | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV52520498; called by muse, mutect2, varscan2
- ESPNL | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs778024556, COSV54541083; called by muse, mutect2, varscan2
- ESYT2 | c.1184A>G p.Q395R (on ENST00000613624; = p.Q319R on NM_020728.3) | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.468); catalogued as rs746020319, COSV51750383, COSV99276583; called by muse, mutect2, varscan2
- ETS2 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs1389242494, COSV62872794; called by muse, mutect2, varscan2
- ETV5 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs779639231, COSV60501408; called by muse, mutect2, varscan2
- EVC | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 17/304 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867240492, COSV53830752; called by muse, mutect2
- EVC | c.2375C>T p.A792V | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs753732049, COSV53831905; called by muse, mutect2, varscan2
- EVC2 | c.3109G>A p.A1037T | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV60392252; called by muse, mutect2, varscan2
- EVI5L | c.1857G>T p.K619N | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV54485309; called by muse, mutect2, varscan2
- EVPL | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs774789564, COSV56910095; called by muse, mutect2, varscan2
- EXOC3 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 74/280 reads (26%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs372707852; called by muse, varscan2
- EXOC3L4 | c.2008C>T p.R670C | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765272210, COSV66295475; called by muse, mutect2, varscan2
- F12 | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 39/155 reads (25%) | catalogued as COSV53691121; called by muse, mutect2, varscan2
- F3 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as rs1157733547, COSV61844952; called by muse, varscan2
- FAM111A | c.1048_1050del p.L350del | In Frame Del (DEL) | VAF 13/102 reads (13%) | catalogued as rs1205108638; called by pindel, varscan2
- FAM13A | c.2461C>T p.R821W | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs148737203; called by muse, mutect2, varscan2
- FAM151A | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.812); catalogued as COSV56363824; called by muse, mutect2, varscan2
- FAM163B | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs762916999, COSV63203877, COSV63206673; called by muse, mutect2, varscan2
- FAM167B | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs981486063; called by muse, mutect2
- FAM181A | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs375576219; called by muse, mutect2, varscan2
- FAM184B | c.2747G>A p.R916H | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV52846115; called by muse, mutect2, varscan2
- FAM200A | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs780218510, COSV68808700; called by muse, mutect2, varscan2
- FAM43B | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs1251047855, COSV100261443; called by muse, mutect2, varscan2
- FAM47C | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.074); catalogued as rs782209571, COSV63725760, COSV63726126; called by muse, mutect2, varscan2
- FAM83H | c.2969C>T p.P990L | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs201196465; called by muse, mutect2, varscan2
- FAM83H | c.2648C>T p.T883M | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.733); catalogued as rs782246101, COSV62028081; called by muse, mutect2, varscan2
- FAM8A1 | c.1024A>G p.T342A | Missense Mutation (SNP) | VAF 18/437 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV52582970; called by muse, mutect2
- FAR2 | c.768G>A p.A256= | Splice Region (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99478660; called by muse, mutect2, varscan2
- FARP2 | c.2938G>A p.V980M | Missense Mutation (SNP) | VAF 86/358 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs145708249; called by muse, mutect2, varscan2
- FASN | c.5263G>A p.A1755T | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60753580; called by muse, mutect2, varscan2
- FAT3 | c.4801C>G p.L1601V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.228); catalogued as COSV53102628; called by mutect2, varscan2
- FAT4 | c.2017G>A p.A673T | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV67884976; called by muse, mutect2, varscan2
- FAT4 | c.5036G>A p.R1679H | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201292031, COSV67884986, COSV67895089; called by muse, mutect2, varscan2
- FBN1 | c.7876C>A p.L2626M | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV100353950; called by muse, mutect2, varscan2
- FBN2 | c.5228G>T p.S1743I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.088); catalogued as COSV52508590; called by muse, mutect2, varscan2
- FBN3 | c.5905G>A p.D1969N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54458974; called by muse, mutect2, varscan2
- FBXL13 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs765103638, COSV57545194; called by mutect2, varscan2
- FBXO24 | c.410G>A p.R137H (on ENST00000241071 / NM_033506.3; = p.R175H on NM_012172.5) | Missense Mutation (SNP) | VAF 56/261 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as rs1056098040, COSV53824013; called by muse, mutect2, varscan2
- FBXO31 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as COSV61147423; called by muse, mutect2, varscan2
- FBXO40 | c.1204T>C p.C402R | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57523574; called by muse, mutect2, varscan2
- FBXO5 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1372484580, COSV57670370; called by muse, mutect2, varscan2
- FBXO6 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.086); catalogued as rs566510540, COSV52416781; called by muse, mutect2, varscan2
- FBXW10 | c.3016G>A p.A1006T | Missense Mutation (SNP) | VAF 24/271 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100111180; called by muse, mutect2
- FBXW8 | c.1076G>A p.R359H (on ENST00000309909; = p.R397H on NM_012174.1) | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs186364302, COSV59298594; called by muse, mutect2, varscan2
- FCAMR | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.254); catalogued as rs1209692605, COSV61367534; called by muse, mutect2, varscan2
- FFAR3 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 66/342 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs138338117; called by muse, mutect2, varscan2
- FGD1 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 78/167 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as rs398124165, COSV64308557; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGF18 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs1316355669, COSV51126013; called by muse, mutect2, varscan2
- FHDC1 | c.1868C>T p.A623V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1457877608, COSV52599331; called by muse, mutect2
- FKBP15 | c.2261G>A p.R754H | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1216550555, COSV53034124; called by muse, mutect2
- FKBP8 | c.688G>A p.A230T (on ENST00000222308 / NM_001308373.2; = p.A231T on NM_012181.5) | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.059); catalogued as COSV55891568; called by muse, mutect2
- FLNC | c.4445T>G p.L1482R | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV100367562; called by muse, mutect2, varscan2
- FLNC | c.4651G>A p.A1551T | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs565918031, CM1512373, COSV100367563; ClinVar: uncertain significance; called by muse, varscan2
- FLRT3 | c.1433G>A p.C478Y | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99426297; called by muse, mutect2
- FLT4 | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs768195465, COSV56106233; called by muse, mutect2, varscan2
- FMNL3 | c.1966C>T p.R656C | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.736); catalogued as rs770930654, COSV53301070; called by muse, mutect2, varscan2
- FN1 | c.1728G>T p.W576C | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60551522; called by muse, varscan2
- FNBP1 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as rs750439648, COSV63086720; called by muse, mutect2, varscan2
- FNTA | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.61); catalogued as rs1220349704, COSV56489426; called by muse, mutect2, varscan2
- FOXA2 | c.1351C>T p.R451W (on ENST00000377115 / NM_153675.3; = p.R457W on NM_021784.5) | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65796127; called by muse, mutect2, varscan2
- FOXB2 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1209607680, COSV65022871; called by muse, mutect2, varscan2
- FOXP1 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV59540837; called by muse, mutect2, varscan2
- FPGS | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs924645605, COSV64675540; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1997A>G p.H666R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); catalogued as COSV100435394; called by muse, mutect2, varscan2
- FRAS1 | c.2834A>C p.Q945P | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV53605933; called by mutect2, varscan2
- FREM1 | c.4111C>A p.L1371I | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV66522432; called by muse, mutect2, varscan2
- FRMD4A | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 54/552 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs754642787, COSV52721262; called by muse, mutect2
- FRMD4A | c.383A>G p.K128R | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as COSV99198392; called by muse, mutect2, varscan2
- FRMPD1 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771951665, COSV66700150; called by muse, mutect2, varscan2
- FRRS1L | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV73746513; called by muse, mutect2, varscan2
- FRZB | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as COSV54553900; called by muse, mutect2, varscan2
- FSCB | c.753dup p.V252Sfs*5 | Frame Shift Ins (INS) | VAF 43/260 reads (17%) | catalogued as rs777325266; called by mutect2, pindel, varscan2
- FSCN1 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.099); catalogued as COSV61017429; called by muse, mutect2, varscan2
- FUT2 | c.478C>A p.L160I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV67179209; called by muse, mutect2, varscan2
- FZD7 | c.1453G>A p.V485I | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.782); catalogued as COSV53809138; called by muse, mutect2, varscan2
- FZD8 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.85); catalogued as COSV65967810; called by muse, mutect2, varscan2
- FZR1 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs760461120, COSV100553353; called by muse, mutect2, varscan2
- GAA | c.645G>T p.E215D | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV56408254; called by muse, mutect2
- GAA | c.2195C>A p.P732H | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56408265; called by muse, mutect2, varscan2
- GAB2 | c.1190A>G p.N397S (on ENST00000361507 / NM_080491.3; = p.N359S on NM_012296.3) | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100416191; called by muse, mutect2, varscan2
- GABBR2 | c.2653C>T p.P885S | Missense Mutation (SNP) | VAF 74/420 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52301282; called by muse, mutect2, varscan2
- GABRA2 | c.839C>A p.P280H | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62916360; called by muse, mutect2, varscan2
- GABRA5 | c.276G>T p.M92I | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as rs1270424788, COSV59478815, COSV59484071; called by muse, mutect2, varscan2
- GABRB2 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs375083192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRD | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 64/244 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs932283828, COSV66080419; called by muse, mutect2, varscan2
- GABRG3 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV61516355, COSV61526912; called by muse, mutect2, varscan2
- GABRR1 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772547976, COSV65619001, COSV65619281; called by muse, mutect2, varscan2
- GALNS | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.098); catalogued as rs779257235, COSV51935975; called by muse, mutect2, varscan2
- GALNTL6 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.181); catalogued as COSV72490637; called by muse, mutect2, varscan2
- GALR1 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.79); catalogued as rs745551553; called by muse, mutect2, varscan2
- GAPVD1 | c.2172A>G p.S724= | Splice Region (SNP) | VAF 70/278 reads (25%) | catalogued as COSV52922462; called by muse, mutect2, varscan2
- GAS2L1 | c.566C>A p.P189H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV53330331; called by muse, mutect2, varscan2
- GATA2 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62003110, COSV62003943; called by muse, mutect2, varscan2
- GATA3 | c.365T>C p.I122T | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1225263875, COSV60517722; called by muse, mutect2, varscan2
- GATAD2A | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 19/247 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1016360626, COSV53069274; called by muse, mutect2
- GATAD2B | c.602C>A p.P201Q | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV64083928, COSV64084277; called by muse, mutect2, varscan2
- GBA | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 61/268 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs79696831, CM000165, COSV59169619; called by muse, mutect2, varscan2
- GBA2 | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV65239375; called by muse, mutect2, varscan2
- GBF1 | c.4525C>T p.R1509W (on ENST00000369983 / NM_001377137.1; = p.R1508W on NM_004193.3) | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749045556, COSV100890280; called by muse, varscan2
- GBX1 | c.974G>T p.S325I | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV52547327; called by muse, mutect2, varscan2
- GCG | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | catalogued as COSV64961189; called by muse, mutect2, varscan2
- GEMIN5 | c.3664G>A p.E1222K | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs953650887, COSV53560074; called by muse, mutect2, varscan2
- GGCX | c.2038C>T p.R680* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as COSV52087073; called by muse, mutect2, varscan2
- GGT5 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.24); catalogued as rs567555612, COSV54069277; called by muse, mutect2, varscan2
- GGT6 | c.1460G>A p.C487Y (on ENST00000574154 / NM_001122890.3; = p.C455Y on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1465281333, COSV54596948; called by muse, mutect2, varscan2
- GHR | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs775194712, COSV50117116; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GIGYF2 | c.2872C>T p.R958W | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768159675, COSV65248690; called by mutect2, varscan2
- GJA9 | c.957A>T p.K319N | Missense Mutation (SNP) | VAF 58/297 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV62532064; called by muse, mutect2, varscan2
- GLA | c.1235C>T p.T412I | Missense Mutation (SNP) | VAF 170/264 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54508954; called by muse, mutect2, varscan2
- GLIPR1L2 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.353); catalogued as rs550463995, COSV57553070, COSV57553633; called by muse, mutect2, varscan2
- GLRA2 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.44); catalogued as rs903978447, COSV54335394; called by muse, mutect2, varscan2
- GMEB2 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 62/283 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56606840; called by muse, mutect2, varscan2
- GNA15 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462808020, COSV53585387; called by muse, mutect2, varscan2
- GNAQ | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs761634659, COSV54111960; called by mutect2, varscan2
- GNB5 | c.643G>A p.G215S (on ENST00000261837 / NM_016194.4; = p.G173S on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1281401564, COSV55899028; called by muse, mutect2, varscan2
- GNG11 | c.5C>A p.P2H | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV50350237; called by muse, mutect2, varscan2
- GNMT | c.236G>A p.G79D | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55102797; called by muse, mutect2, varscan2
- GOLGA3 | c.3785G>A p.R1262Q | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as rs752656332, COSV52629731, COSV99205249; called by muse, mutect2, varscan2
- GORAB | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as rs374614330, CD086061; called by muse, mutect2, varscan2
- GP1BA | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.95); PolyPhen benign (0.006); catalogued as rs780652188, COSV56699316; called by muse, mutect2, varscan2
- GP5 | c.439A>G p.N147D | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as COSV55463897; called by muse, mutect2, varscan2
- GPR152 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs754807161, COSV56888046; called by muse, varscan2
- GPR155 | c.1822G>T p.E608* | Nonsense Mutation (SNP) | VAF 33/154 reads (21%) | catalogued as COSV55038618; called by muse, mutect2, varscan2
- GPR162 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV50590325; called by muse, mutect2, varscan2
- GPR37 | c.1289C>T p.T430I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV100390497; called by muse, mutect2, varscan2
- GPR50 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs1002895906, COSV54437099; called by muse, mutect2
- GPR62 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV100436872; called by mutect2, varscan2
- GPR63 | c.1204C>T p.R402* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as rs955123836, COSV100013091, COSV57740915; called by muse, mutect2, varscan2
- GPR68 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs969683832, COSV53176215; called by muse, mutect2, varscan2
- GPSM1 | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764332882, COSV99395818; called by muse, mutect2, varscan2
- GPX5 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV101297252, COSV69079322; called by muse, mutect2, varscan2
- GRAMD2B | c.959T>G p.L320R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.265); catalogued as COSV99586905; called by muse, mutect2
- GREM2 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.536); catalogued as rs1044647734, COSV58947633; called by muse, mutect2, varscan2
- GRHL1 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs370119892; called by muse, mutect2, varscan2
- GRID2IP | c.3193C>T p.H1065Y | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1488521801, COSV70692333; called by muse, mutect2, varscan2
- GRIN3A | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV100701343; called by muse, mutect2, varscan2
- GRM5 | c.1355A>T p.D452V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV59602402; called by muse, mutect2, varscan2
- GSDMA | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs752835991, COSV52857246; called by muse, mutect2, varscan2
- GSE1 | c.3256C>T p.P1086S | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as COSV53671523; called by muse, mutect2, varscan2
- GSTA4 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.619); catalogued as rs139066992, COSV63955067; called by muse, mutect2, varscan2
- GSTM3 | c.544T>C p.F182L | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.34); catalogued as COSV99860135; called by muse, mutect2, varscan2
- GSX2 | c.403C>A p.H135N | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.097); catalogued as rs1368232104, COSV58842779; called by muse, mutect2
- GTF2E2 | c.386A>G p.K129R | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.777); catalogued as rs1320180200, COSV63478301; called by muse, mutect2, varscan2
- GTF2H4 | c.1142C>A p.P381H | Missense Mutation (SNP) | VAF 61/305 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.463); catalogued as COSV52558624; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 64/508 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs1554532867, COSV100441049; called by muse, mutect2, varscan2
- GTSF1 | c.258G>T p.R86S | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV59938604; called by muse, mutect2, varscan2
- GUCY2C | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs142517628; called by muse, mutect2, varscan2
- GZMH | c.640G>T p.G214C | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99361789; called by muse, mutect2, varscan2
- H4-16 | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV100797603; called by muse, mutect2, varscan2
- HACE1 | c.1385G>A p.C462Y | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV99493232; called by muse, varscan2
- HACE1 | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1455900509, COSV53501751; called by muse, varscan2
- HAGHL | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.164); catalogued as COSV52401806; called by muse, mutect2, varscan2
- HAUS1 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 41/412 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.308); catalogued as rs766441279, COSV99958706; called by muse, mutect2, varscan2
- HCLS1 | c.1415G>A p.G472D | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57523579; called by muse, mutect2, varscan2
- HDAC5 | c.2793del p.I932Lfs*14 | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | catalogued as COSV52242263; called by mutect2, pindel, varscan2
- HDLBP | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV60494686; called by muse, mutect2, varscan2
- HEATR1 | c.5689A>G p.I1897V | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV63980843; called by muse, mutect2, varscan2
- HEATR1 | c.956A>G p.K319R | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.25); catalogued as COSV63980850; called by muse, mutect2, varscan2
- HECW1 | c.4714C>T p.H1572Y | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101222703; called by muse, mutect2, varscan2
- HEG1 | c.1619G>A p.G540D | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV60761508; called by muse, mutect2, varscan2
- HELZ2 | c.6674C>T p.S2225L (on ENST00000467148 / NM_001037335.2; = p.S1656L on NM_033405.3) | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1170034006, COSV101427510; called by muse, mutect2, varscan2
- HELZ2 | c.2156G>A p.R719H (on ENST00000467148 / NM_001037335.2; = p.R150H on NM_033405.3) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100915416; called by muse, mutect2, varscan2
- HERC2 | c.7331G>A p.R2444H | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as rs773782442, COSV99870468; called by muse, mutect2, varscan2
- HEXD | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 63/257 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs774650789, COSV60062862; called by muse, mutect2, varscan2
- HGS | c.1928G>T p.G643V | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs201755663, COSV61267638; called by muse, mutect2, varscan2
- HID1 | c.2272C>T p.R758C | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs868663975, COSV60913208; called by muse, mutect2, varscan2
- HIF3A | c.530G>A p.R177H (on ENST00000377670 / NM_152795.4; = p.R108H on NM_022462.4) | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs371292313; called by muse, mutect2, varscan2
- HJV | c.575C>A p.P192H (on ENST00000336751 / NM_213653.4; = p.P79H on NM_145277.5) | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM0911002, COSV60951853; called by muse, mutect2, varscan2
- HK1 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762936110, COSV53854593; called by muse, mutect2, varscan2
- HLTF | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); catalogued as rs527812739, COSV59503687; called by muse, mutect2, varscan2
- HMCN1 | c.4414G>A p.A1472T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs763411017, COSV54949176; called by muse, mutect2, varscan2
- HMCN1 | c.11050C>A p.L3684I | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.462); catalogued as COSV54895359; called by muse, mutect2, varscan2
- HMCN2 | c.13564G>A p.A4522T | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1159130866, COSV70934350; called by muse, varscan2
- HNRNPC | c.299C>A p.S100Y | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV60144759; called by muse, mutect2, varscan2
- HOOK2 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs567279935, COSV53401861; called by muse, mutect2, varscan2
- HOPX | c.161G>A p.R54H (on ENST00000317745; = p.R72H on NM_032495.6) | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs150574089; ClinVar: likely benign; called by muse, mutect2, varscan2
- HOXD1 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as rs751102076, COSV58923360; called by muse, mutect2, varscan2
- HR | c.2333T>C p.M778T | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV57191741; called by muse, mutect2, varscan2
- HRNR | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 77/321 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV100912821, COSV64260943; called by muse, mutect2, varscan2
- HS3ST5 | c.882C>A p.C294* | Nonsense Mutation (SNP) | VAF 13/83 reads (16%) | catalogued as COSV100450178; called by muse, mutect2, varscan2
- HSD11B2 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 73/230 reads (32%) | SIFT tolerated (0.84); PolyPhen benign (0.031); catalogued as rs560632514, COSV52096944; called by muse, mutect2, varscan2
- HSD17B1 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs1456238264, COSV56797611; called by muse, mutect2, varscan2
- HSD17B12 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 62/257 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs764576855, COSV53498884; called by muse, mutect2, varscan2
- HSPA12A | c.373C>A p.L125M | Missense Mutation (SNP) | VAF 73/243 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV65021991; called by muse, mutect2, varscan2
- HSPA4L | c.444dup p.T149Yfs*2 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | catalogued as rs752931412; called by pindel, varscan2
- HSPG2 | c.11705G>A p.R3902Q | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs375127656; called by muse, mutect2, varscan2
- HSPG2 | c.7872C>T p.H2624= | Splice Region (SNP) | VAF 76/306 reads (25%) | catalogued as rs749008859, COSV65970955; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HTR2C | c.443T>C p.I148T | Missense Mutation (SNP) | VAF 74/121 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52220079, COSV99347962; called by muse, varscan2
- HTT | c.5827G>A p.V1943I | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs201639415, COSV100750329; called by muse, mutect2, varscan2
- HUNK | c.2137C>T p.Q713* | Nonsense Mutation (SNP) | VAF 22/81 reads (27%) | catalogued as rs778884120, COSV54227516; called by muse, mutect2, varscan2
- HYAL1 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1553713391, COSV56497407; called by muse, mutect2, varscan2
- HYDIN | c.15208C>T p.R5070W | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs577654275, COSV101125259, COSV66638558; called by muse, mutect2, varscan2
- IFFO2 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 59/284 reads (21%) | catalogued as COSV62913118; called by muse, mutect2, varscan2
- IFNA8 | c.492G>A p.W164* | Nonsense Mutation (SNP) | VAF 11/121 reads (9%) | catalogued as COSV66504542; called by muse, mutect2, varscan2
- IFT172 | c.3427G>A p.E1143K | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs144121974; called by muse, mutect2, varscan2
- IGF2R | c.3973C>T p.R1325C | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450812761, COSV63628466; called by muse, mutect2, varscan2
- IGHD | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 48/185 reads (26%) | catalogued as COSV101162788; called by muse, mutect2, varscan2
- IGSF3 | c.424A>C p.I142L | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.94); catalogued as COSV59589809; called by muse, mutect2, varscan2
- IGSF9B | c.3071C>T p.T1024M | Missense Mutation (SNP) | VAF 96/431 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs762381409, COSV58066767; called by muse, mutect2, varscan2
- IKZF4 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56267956; called by muse, mutect2, varscan2
- IL15RA | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.058); catalogued as rs147420996; called by muse, mutect2, varscan2
- IL1R2 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs759636734, COSV60206891; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1193-1G>T p.X398_splice | Splice Site (SNP) | VAF 28/49 reads (57%) | catalogued as COSV61153941; called by muse, mutect2, varscan2
- IL1RL2 | c.1082T>C p.I361T | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV51814766; called by muse, mutect2, varscan2
- IL4R | c.1391C>A p.P464H | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV50141591; called by muse, mutect2, varscan2
- ILF3 | c.950G>A p.S317N | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV51556768; called by muse, mutect2, varscan2
- INF2 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as rs1480273257, COSV57980000; called by muse, mutect2, varscan2
- INO80E | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs145127821; called by muse, mutect2, varscan2
- INPP5A | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs374027590; called by muse, mutect2, varscan2
- INPPL1 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1460429409, COSV53354991; called by muse, mutect2, varscan2
- INPPL1 | c.3424C>T p.R1142C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.348); catalogued as rs374001069; called by muse, mutect2, varscan2
- INSRR | c.2378C>T p.A793V | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.118); catalogued as COSV63872607; called by muse, mutect2, varscan2
- INTS1 | c.2210C>T p.A737V | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs1196276181, COSV67177210; called by muse, mutect2, varscan2
- INTS11 | c.140A>G p.D47G | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100027932; called by muse, mutect2, varscan2
- INTS13 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs772898480, COSV53901458; called by muse, mutect2, varscan2
- INTS7 | c.1567G>T p.G523* | Nonsense Mutation (SNP) | VAF 35/124 reads (28%) | catalogued as COSV100877354; called by muse, mutect2, varscan2
- INTS9 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV68433918; called by muse, mutect2, varscan2
- INTU | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV56539480; called by muse, mutect2, varscan2
- INVS | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV52441215; called by muse, mutect2, varscan2
- IPO13 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1190518168, COSV64894084; called by muse, mutect2, varscan2
- IQSEC2 | c.1085G>A p.R362H (on ENST00000642864 / NM_001111125.3; = p.R157H on NM_015075.2) | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs868913552, COSV64725026, COSV64725055; called by muse, mutect2
- IRS4 | c.3262C>T p.R1088C | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as COSV64533502, COSV64535790; called by muse, mutect2, varscan2
- IRX1 | c.406C>A p.R136S | Missense Mutation (SNP) | VAF 45/373 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57358324; called by muse, mutect2, varscan2
- IRX5 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV100315620, COSV58058530; called by muse, mutect2, varscan2
- IRX6 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764325539, COSV99306159; called by muse, mutect2, varscan2
- ITGA10 | c.2990G>A p.G997E | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.534); catalogued as COSV100994664; called by muse, mutect2, varscan2
- ITGA10 | c.1838G>A p.R613Q | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as rs781987259, COSV65195979; called by muse, mutect2, varscan2
- ITGA3 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs141797951; called by muse, mutect2, varscan2
- ITGA3 | c.1252C>A p.H418N | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.035); catalogued as COSV50309766; called by muse, mutect2, varscan2
- ITGA4 | c.2249+2T>A p.X750_splice | Splice Site (SNP) | VAF 14/74 reads (19%) | catalogued as COSV67897011; called by muse, mutect2, varscan2
- ITGAE | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 78/311 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758972428, COSV53993054; called by muse, mutect2, varscan2
- ITGB1BP2 | c.178A>G p.T60A | Missense Mutation (SNP) | VAF 77/127 reads (61%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.908); catalogued as rs745484881, COSV52137169; called by muse, mutect2, varscan2
- ITGB2 | c.1387G>A p.V463M (on ENST00000302347; = p.V439M on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs372056902; called by muse, mutect2, varscan2
- ITPR1 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs1426792994, COSV100229243; called by muse, mutect2, varscan2
- ITPR1 | c.6812G>A p.R2271H (on ENST00000354582; = p.R2216H on NM_002222.7) | Missense Mutation (SNP) | VAF 88/377 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs753036913, COSV56981630; called by muse, mutect2, varscan2
- ITPR3 | c.4129G>A p.E1377K | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs933450961, COSV65408018; called by muse, mutect2, varscan2
- ITPR3 | c.5083C>A p.L1695I | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV65408382; called by muse, mutect2, varscan2
- ITPRID2 | c.2111G>A p.S704N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs1408427130, COSV57471177; called by muse, mutect2, varscan2
- ITSN2 | c.4622C>T p.A1541V | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs371101764; called by muse, mutect2, varscan2
- JAG1 | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54756085; called by muse, mutect2, varscan2
- JAZF1 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as COSV52234320, COSV52242006; called by muse, mutect2, varscan2
- KANK2 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0.056); catalogued as COSV62007674; called by muse, mutect2, varscan2
- KAT6B | c.4121G>A p.G1374E | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV54743294, COSV54745814; called by muse, mutect2, varscan2
- KATNB1 | c.1060T>C p.S354P | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV65550000; called by muse, mutect2
- KATNIP | c.4279C>T p.R1427* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as rs1449567969, COSV55179117; called by muse, varscan2
- KCNA6 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 46/246 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV54974531; called by muse, mutect2, varscan2
- KCNB1 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65567699; called by muse, mutect2, varscan2
- KCNF1 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 24/85 reads (28%) | catalogued as COSV54462994; called by muse, mutect2, varscan2
- KCNF1 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV54463008; called by muse, mutect2, varscan2
- KCNG1 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766312668, COSV65368896; called by mutect2, varscan2
- KCNH5 | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.904); catalogued as COSV100525163; called by muse, mutect2, varscan2
- KCNH6 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 63/224 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs752536722, COSV59002852; called by muse, mutect2, varscan2
- KCNJ4 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57856883; called by muse, mutect2, varscan2
- KCNJ5 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as COSV57965467; called by muse, mutect2, varscan2
- KCNJ5 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.107); catalogued as rs372447456; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNQ5 | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.178); catalogued as rs1562230186, COSV59658525; called by muse, mutect2, varscan2
- KCNU1 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781758175, COSV67754429; called by muse, mutect2, varscan2
- KCP | c.3205C>T p.R1069C (on ENST00000620378; = p.R1129C on NM_001366122.1) | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs1563021357, COSV99925764; called by muse, mutect2, varscan2
- KCTD16 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 11/215 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV72579174; called by muse, mutect2
- KCTD16 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as rs1434066147, COSV72578389; called by muse, mutect2, varscan2
- KCTD19 | c.2717T>C p.I906T | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV58572477; called by muse, mutect2, varscan2
- KCTD20 | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 48/192 reads (25%) | catalogued as rs1447196047, COSV54803118; called by muse, mutect2, varscan2
- KCTD3 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99379343; called by muse, mutect2
- KDF1 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as rs1433039862, COSV57671232; called by muse, mutect2, varscan2
- KDM4B | c.1712C>T p.T571M | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs750077858, COSV50217579; called by muse, mutect2, varscan2
- KDM5B | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1167029210, COSV52507140; called by muse, mutect2, varscan2
- KDM6B | c.1259C>A p.P420H | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.282); catalogued as COSV54680770; called by muse, mutect2, varscan2
- KDM6B | c.3727G>A p.V1243M | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs368880082; called by muse, mutect2, varscan2
- KDM7A | c.2105T>C p.V702A | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99133875; called by muse, mutect2, varscan2
- KEAP1 | c.667C>A p.L223M | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99407259; called by muse, mutect2, varscan2
- KIAA0825 | c.3112G>A p.A1038T | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.095); catalogued as COSV70248289; called by muse, mutect2, varscan2
- KIAA1549L | c.5117-1G>T p.X1706_splice (on ENST00000321505; = p.X2003_splice on NM_012194.3) | Splice Site (SNP) | VAF 18/118 reads (15%) | catalogued as COSV58586828; called by muse, mutect2, varscan2
1,720 further variants in this file (963 protein-altering or splice-affecting, 605 silent, 152 other) are not listed here.
